Somatic mutation profile of tumor specimen TCGA-DU-7013-01A (aliquot TCGA-DU-7013-01A-11D-2024-08) from TCGA case TCGA-DU-7013, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 59.8 years (21,824 days).
Specimen TCGA-DU-7013-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13255904-b3f0-4b72-b6e2-33e7a27e0efb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7013-10A (Blood Derived Normal), aliquot TCGA-DU-7013-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a22ee23a-3054-4ab4-95fb-faa2d6c672be

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 25, Silent 10, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 28/30 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGEF1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868960086, COSV61526025; called by muse, mutect2
- CASKIN1 | c.2960G>A p.S987N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV58213354; called by muse, mutect2, varscan2
- CEL | c.1174G>A p.E392K (on ENST00000673714; = p.E389K on NM_001807.6) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1226275795, COSV100672757; called by mutect2, varscan2
- CYP2C19 | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV64907218; called by muse, mutect2, varscan2
- DNAH1 | c.10715G>A p.R3572Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs761172905, COSV70227435, COSV70230021; called by muse, mutect2, varscan2
- EDAR | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs770292889, COSV51500881; called by muse, mutect2, varscan2
- FGA | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs760992799, COSV57392359; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGD5 | c.1181G>C p.C394S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as COSV53239530; called by muse, mutect2, varscan2
- FMC1-LUC7L2 | c.193A>C p.T65P | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52545875; called by muse, mutect2, varscan2
- GK2 | c.1451T>C p.M484T | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV62626310; called by muse, mutect2, varscan2
- KCNH1 | c.2628G>C p.K876N (on ENST00000271751 / NM_172362.3; = p.K849N on NM_002238.4) | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); catalogued as COSV55073853; called by muse, mutect2, varscan2
- KRT6B | c.1082A>G p.E361G | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as COSV52882726; called by muse, mutect2, varscan2
- MDGA2 | c.2065G>A p.G689R (on ENST00000399232 / NM_001113498.2; = p.G391R on NM_182830.4) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.887); catalogued as COSV62083444; called by muse, mutect2, varscan2
- MSLNL | c.1000T>C p.C334R | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53500438; called by muse, mutect2, varscan2
- MUC5AC | c.15058G>A p.V5020M | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.875); catalogued as rs751208171, COSV64370744; called by muse, mutect2
- NDST3 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs764215296, COSV56615244; called by muse, varscan2
- NLRC4 | c.263-1G>A p.X88_splice | Splice Site (SNP) | VAF 24/52 reads (46%) | catalogued as COSV61591900; called by muse, mutect2, varscan2
- NLRP9 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as rs571820588, COSV60461115; called by muse, mutect2, varscan2
- NPIPB15 | c.324G>T p.W108C | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV101466041; called by mutect2, varscan2
- NUP155 | c.305G>C p.C102S (on ENST00000231498 / NM_153485.3; = p.C43S on NM_004298.4) | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.152); catalogued as COSV51528269; called by muse, mutect2, varscan2
- OR9G1 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.232); catalogued as rs1215453516, COSV56449398; called by muse, mutect2, varscan2
- R3HDML | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53835483; called by muse, mutect2, varscan2
- SETX | c.4613G>A p.R1538Q | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs749550863, COSV56381252; called by muse, mutect2, varscan2
- ZMYM2 | c.2801T>C p.I934T | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs745443971, COSV67033052; called by muse, mutect2, varscan2
- ZSCAN31 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.259); catalogued as COSV60180505; called by muse, mutect2, varscan2
- TMPRSS11F | c.1056del p.I353* | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- ADH1A | c.321G>A p.P107= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs538543042, COSV52924557; called by muse, mutect2, varscan2
- AIPL1 | c.792G>A p.V264= | Silent (SNP) | VAF 22/27 reads (81%) | catalogued as COSV51506291; called by muse, mutect2, varscan2
- GUCA1B | c.57G>A p.A19= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs368778664; called by muse, mutect2
- MYH6 | c.5025C>T p.I1675= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs763337280, COSV62447976; called by muse, mutect2, varscan2
- NOS1 | c.1254G>A p.S418= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as rs946356254, COSV57608982; called by muse, mutect2, varscan2
- PLAG1 | c.1098C>T p.G366= | Silent (SNP) | VAF 101/173 reads (58%) | catalogued as rs199920673, COSV57610085; called by muse, mutect2, varscan2
- POLR2E | c.393G>A p.L131= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV53123634; called by muse, mutect2, varscan2
- SLC16A3 | c.915C>T p.N305= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as rs765079266, COSV58363880; called by muse, mutect2, varscan2
- SPTB | c.2727C>T p.L909= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs200197418; called by muse, mutect2, varscan2
- TLR4 | c.1152C>A p.G384= (on ENST00000355622 / NM_138554.5; = p.G344= on NM_003266.4) | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV62922739; called by muse, mutect2, varscan2
